RC case RC-B6SQ — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7ea94c43-ad56-4b17-b825-2592ba4d3f35

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1965; Vital status: Alive; Country of birth: United States.

Diagnoses (6)
1. Angioimmunoblastic T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9705/3; ICD-10 code: C84; Tissue or organ of origin: Lymph nodes of multiple regions; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: primary; Age at diagnosis: 53.7 years (19,606 days); Year of diagnosis: 2019; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Ann arbor b symptoms described array: Weight Loss / Night Sweats; Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): Low Risk; Sites of involvement: Lymph Node, Cervical / Lymph Node, Hilar / Lymph Node, Inguinal / Lymph Node, Mediastinal / Lymph Node, Para-Aortic.
   Pathology details: Greatest tumor dimension: 4.6 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Oxaliplatin + Romidepsin; Initial disease status: Initial Diagnosis; Days to treatment start: 27 days; Days to treatment end: 120 days; Number of cycles: 5; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Clinical trial indicator: Yes; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Days to treatment start: 159 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, NOS.
2. Prior malignancy of the breast (histology not recorded by GDC). Laterality: Right; Age at diagnosis: 49.3 years (18,000 days); Year of diagnosis: 2014; Days to diagnosis: -1,606 days (-4.4 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,606 days (-4.4 years); Treatment anatomic sites: Other.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -1,590 days (-4.4 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Anastrozole; Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Tamoxifen; Treatment anatomic sites: Body, total.
3. Prior malignancy of the rectum (histology not recorded by GDC). Age at diagnosis: 49.5 years (18,093 days); Year of diagnosis: 2014; Days to diagnosis: -1,513 days (-4.1 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,513 days (-4.1 years); Treatment anatomic sites: Other.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Capecitabine; Days to treatment start: -1,453 days (-4.0 years); Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.
4. MALT lymphoma: ICD-O-3 morphology code: 9699/3; Tissue or organ of origin: Lymph node, NOS; Laterality: Bilateral; Classification of tumor: Prior primary; Age at diagnosis: 50.9 years (18,577 days); Year of diagnosis: 2016; Days to diagnosis: -1,029 days (-2.8 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bendamustine + Rituximab; Days to treatment start: -996 days (-2.7 years); Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
5. Hodgkin lymphoma, NOS: ICD-O-3 morphology code: 9650/3; Tissue or organ of origin: Lymph node, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 52.4 years (19,153 days); Year of diagnosis: 2017; Days to diagnosis: -453 days (-1.2 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bleomycin + Dacarbazine + Doxorubicin + Vinblastine; Regimen or line of therapy: ABVD; Days to treatment start: -444 days (-1.2 years); Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
6. Subsequent primary of the kidney (histology not recorded by GDC). Age at diagnosis: 57.3 years (20,934 days); Days to diagnosis: 1,328 days (3.6 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 1,328 days (3.6 years); Treatment outcome: Complete Response.

Follow-up (4 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Days to follow up: 70 days; Disease response: Partial Response.
- Day 119 (end of treatment course 1): Disease response: Tumor Free.
- Day 1,505 (within 2 months after completion of first-course treatment): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.

Molecular and laboratory tests
- Lactate Dehydrogenase 325 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 93 kg; Height: 167 cm; BMI: 33.3.
- Timepoint category: Prior to Diagnosis; Risk factors: Hodgkin Lymphoma / Skin Rash.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 19.5; Tobacco smoking onset year: 1983.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B6SQ-NB1-A: Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample RC-B6SQ-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B6SQ-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
